Surgical pathology report (de-identified scan), TCGA case TCGA-CE-A13K, project TCGA-THCA (Thyroid Carcinoma), tissue source site ILSBio, specimen TCGA-CE-A13K-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3

Carcinoma, papillary thyroid 8260/3

Site: Thyroid, NOS C73.9 1/28/11 *hw*

Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
min		min		min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Thyroid tumor	4.5 x 4 x 2 cm	left	3 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT3	N1	M0	Stage: I
Notes: nodes in Nitrogen (2 vials)			
UUID: 21076911-FE79-445E-BE30-A0DAF4D872C6 TCGA-CE-A13K-01A-PR Redacted			

HI/AA Discrepancy		☒
Du./Synchronous Primary Noted		
Reviewed Initial	hw	hw

[page 2 of 3]
ID#:

Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse					Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration					Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						
Cellular Differentiation											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		
Cellular Differentiation: Well ☒ Moderate ☐ Poor ☐											
Nuclear Appearance											
Nuclear Atypia:						0	I	II	III		
Aniso Nucleosis											
Hyperchromatism											
Nucleolar Prominent											
Multinucleated Giant Cell											
Mitotic Activity											
Nuclear Grade:											

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: papillary carcinoma Grade:
(left node positive)

Comments:

Principal Investigator

Pathologist

Date

[page 3 of 3]
1CD-0-3

Carcinoma, papillary thyroid 8260/3

Site: thyroid, NOS C73.9 1/28/11 hr

CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse				Streaming			
Mosaic				Storiform			
Necrosis				Fibrosis			
Lymphocytic Infiltration				Palisading			
Vascular Invasion				Cystic Degeneration			
Clusterized				Bleeding			
Alveolar Formation				Myxoid Change			
Indian File				Psammoma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell			Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		
Otherwise Specified: 61 90% D2 90% D3 90% D4 90%											

2. Cellular Differentiation:

Well	Moderately	Poor

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				
Hyperchromatism				
Nucleolar Prominent				
Multinucleated Giant Cell				
Mitotic Activity				
Nuclear Grade				

Histological Diagnosis: Papillary Thyroid Carcinoma, G1

Comments: M1, M2 Carcinoma metastasized to LN.

Date

(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Source: NCI Genomic Data Commons file 2888790c-4da3-439d-b363-63507e2f89f2 (TCGA-CE-A13K.21076911-FE79-445E-BE30-A0DAF4D872C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).